Somatic mutation profile of tumor specimen TCGA-EJ-A8FN-01A (aliquot TCGA-EJ-A8FN-01A-11D-A34U-08) from TCGA case TCGA-EJ-A8FN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.9 years (21,506 days).
Specimen TCGA-EJ-A8FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed18407f-e34c-4ebc-9124-18f97ccf94cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A8FN-10A (Blood Derived Normal), aliquot TCGA-EJ-A8FN-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/255aa05b-301a-4978-8455-28c146033a5d

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1845C>A p.S615R | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752034012, COSV55941319, COSV99710359; called by muse, mutect2, varscan2
- ACBD5 | c.989A>G p.N330S (on ENST00000375888 / NM_001352568.1; = p.N321S on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs768365855, COSV65518548; called by muse, mutect2, varscan2
- BAHCC1 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV100311576; called by muse, mutect2
- BBS4 | c.284T>A p.V95D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99166434; called by muse, mutect2, varscan2
- BSX | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as rs772877086, COSV100545231, COSV58006110; called by muse, mutect2, varscan2
- CLCA4 | c.2405A>G p.D802G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100991105; called by muse, mutect2
- COL11A1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs769449348, COSV100616347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMAC2 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781788109, COSV99700505; called by muse, mutect2, varscan2
- DPP10 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV59705251; called by muse, mutect2, varscan2
- FRMPD1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780248862, COSV66703083; called by muse, mutect2, varscan2
- HOXA9 | c.496A>T p.R166* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100604361, COSV100604395; called by muse, mutect2, varscan2
- IMPDH2 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100455025; called by muse, mutect2, varscan2
- ITFG1 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV100066877; called by muse, mutect2, varscan2
- KMT2B | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.272); catalogued as COSV99719496; called by muse, mutect2, varscan2
- L1CAM | c.198-1G>A p.X66_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100649093; called by muse, mutect2, varscan2
- LILRB5 | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100300344; called by muse, mutect2, varscan2
- LIMD1 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99836921; called by muse, mutect2, varscan2
- LMOD2 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV71755868; called by muse, mutect2, varscan2
- MOV10 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100659537; called by muse, mutect2, varscan2
- NAV2 | c.4912A>G p.K1638E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100216797; called by muse, mutect2, varscan2
- PACSIN1 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1431619310, COSV99763063; called by muse, mutect2
- PPP2R5E | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV61744773; called by muse, mutect2, varscan2
- PSG4 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.152); catalogued as rs867668965, COSV99736974; called by muse, mutect2, varscan2
- SASS6 | c.1367A>T p.K456I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99790788; called by muse, mutect2, varscan2
- SLC52A2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs782269382, COSV100095695; called by muse, mutect2
- STRBP | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100724176; called by muse, mutect2, varscan2
- TGFBI | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373585898, COSV59352636; called by muse, mutect2, varscan2
- TRIM67 | c.1493A>C p.Q498P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100792114; called by muse, mutect2, varscan2
- KMT2D | c.2192_2193del p.E731Afs*17 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1497dup p.E500Rfs*29 | Frame Shift Ins (INS) | VAF 26/51 reads (51%) | called by mutect2, pindel, varscan2
- DPP10 | c.66G>T p.L22= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100064219; called by muse, mutect2, varscan2
- GLYATL2 | c.343A>C p.R115= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as rs1436525488, COSV54849376; called by muse, mutect2, varscan2
- LMAN2L | c.597C>T p.G199= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99382973, COSV99383329; called by muse, mutect2, varscan2
- PRPF31 | c.774G>A p.T258= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs778556890, COSV100319959; called by muse, mutect2, varscan2
- RFX3 | c.633C>T p.H211= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100175004; called by muse, mutect2
- SIGLEC9 | c.741C>T p.D247= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs774357117, COSV51582435, COSV51585838; called by muse, mutect2, varscan2
- SNORD3B-2 | n.122T>G | RNA (SNP) | VAF 20/186 reads (11%) | catalogued as rs753918930; called by muse, varscan2
